Somatic mutation profile of tumor specimen TCGA-90-7766-01A (aliquot TCGA-90-7766-01A-21D-2122-08) from TCGA case TCGA-90-7766, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.7 years (24,354 days).
Specimen TCGA-90-7766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a86802f-e37b-4fc7-af0b-0ec919f1ac47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-7766-10A (Blood Derived Normal), aliquot TCGA-90-7766-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/260fcd88-5449-470a-9843-59b8673de14a

The open-access MAF lists 119 somatic variants for this specimen: 97 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 17, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 3, RNA 3, Frame Shift Ins 2, Intron 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- ABCC12 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100253009; called by muse, mutect2, varscan2
- ADGRB3 | c.4009C>T p.H1337Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV53233457, COSV53263338, COSV53263707; called by muse, mutect2, varscan2
- AGTPBP1 | c.3563G>A p.S1188N (on ENST00000357081 / NM_001330701.2; = p.S1148N on NM_015239.2) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); catalogued as COSV100430019; called by mutect2, varscan2
- AGTR2 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV100903601; called by muse, mutect2, varscan2
- AHRR | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.129); catalogued as rs1318530723, COSV100327759; called by muse, mutect2, varscan2
- AKT1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV62577048, COSV99050883; called by muse, mutect2, varscan2
- ANKRD16 | c.535+1G>T p.X179_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99510507; called by muse, mutect2, varscan2
- ANKRD34A | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100041353; called by muse, mutect2, varscan2
- ASMTL | c.11G>T p.C4F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV101187865; called by muse, mutect2, varscan2
- CD1D | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100939633; called by muse, mutect2, varscan2
- CD40LG | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV101033523; called by muse, mutect2, varscan2
- CDSN | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV99457082; called by muse, mutect2, varscan2
- CHI3L2 | c.1046T>A p.L349* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100869308; called by muse, mutect2, varscan2
- CHRND | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99286031; called by muse, mutect2, varscan2
- CXorf58 | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV101003054; called by muse, mutect2, varscan2
- CYBB | c.606T>G p.F202L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as CP005266, COSV101059801; called by muse, mutect2, varscan2
- DCAF8 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV100470705; called by muse, mutect2, varscan2
- DEFB119 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.414); catalogued as COSV100191071; called by muse, mutect2, varscan2
- DNAH7 | c.10279T>C p.C3427R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100416520; called by muse, mutect2, varscan2
- DROSHA | c.2742G>T p.R914S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100757753; called by muse, mutect2, varscan2
- DZIP3 | c.1688A>G p.H563R | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.966); catalogued as COSV100847955; called by muse, mutect2, varscan2
- ERBB4 | c.1947-1G>C p.X649_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99629365; called by muse, mutect2, varscan2
- FRY | c.6467T>C p.F2156S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969694; called by muse, mutect2, varscan2
- FUT9 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765166497, COSV100134026; called by muse, mutect2, varscan2
- GCNA | c.1872C>A p.H624Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101031697; called by muse, mutect2
- GPATCH2 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100861414; called by muse, mutect2, varscan2
- GPR139 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58505269; called by muse, mutect2, varscan2
- GPR50 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs760732722, COSV99506433; called by muse, mutect2, varscan2
- GPRC6A | c.1596G>C p.K532N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114592; called by muse, mutect2, varscan2
- GZF1 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100582624; called by muse, mutect2, varscan2
- HAUS1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV99959548; called by muse, mutect2, varscan2
- HPS4 | c.1797C>A p.S599R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100404575; called by muse, mutect2, varscan2
- IGHJ6 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | PolyPhen probably damaging (0.981); catalogued as rs111729691; called by muse, mutect2
- INO80C | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV99358529; called by muse, mutect2, varscan2
- ITGAE | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99561337; called by muse, mutect2
- LAMA4 | c.670T>C p.C224R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100038997; called by muse, mutect2, varscan2
- LRP2 | c.5003C>A p.A1668D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99789638; called by muse, mutect2, varscan2
- LTBP4 | c.2933G>T p.C978F (on ENST00000308370 / NM_001042544.1; = p.C941F on NM_003573.2) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52590917, COSV99198996; called by muse, mutect2, varscan2
- MAN1A1 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63786533; called by muse, mutect2, varscan2
- MAS1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs532916357, COSV53122252; called by muse, mutect2, varscan2
- MDC1 | c.3938G>A p.R1313K | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV100903003; called by muse, mutect2, varscan2
- MLF2 | c.746G>C p.*249Sext*12 | Nonstop Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as COSV99180109; called by muse, mutect2, varscan2
- NCOA2 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs1216816195, COSV99144989; called by muse, mutect2, varscan2
- NCOR1 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1388770237, COSV51994187, COSV99246285; called by muse, mutect2, varscan2
- NEB | c.17387G>A p.R5796Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775595412, COSV50842411, COSV51422946; called by muse, mutect2, varscan2
- NEUROD6 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99774054; called by muse, mutect2, varscan2
- NLRC3 | c.194G>T p.R65M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100073120; called by muse, mutect2, varscan2
- OMD | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1466057537, COSV100979072; called by muse, mutect2, varscan2
- OMG | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV99907920; called by muse, mutect2, varscan2
- OR11G2 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100640007; called by muse, mutect2, varscan2
- OR2L3 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV100742019; called by muse, mutect2, varscan2
- OR5A1 | c.930G>C p.R310S | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100118443; called by muse, mutect2, varscan2
- OR5F1 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53548778, COSV99558826; called by muse, mutect2, varscan2
- OR5P2 | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV100271417; called by muse, mutect2, varscan2
- OR5T2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1397709264, COSV100507008, COSV57590715; called by muse, mutect2, varscan2
- OR8H3 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100539105; called by muse, mutect2, varscan2
- OR8K3 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as COSV100449850; called by muse, mutect2, varscan2
- PARVA | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV100616775; called by muse, varscan2
- PASD1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV64855711; called by muse, mutect2, varscan2
- PFKL | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62465876; called by muse, mutect2
- PHKA1 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV59809579; called by muse, mutect2, varscan2
- PKHD1 | c.4139T>C p.V1380A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748168017, CM052342, COSV100584028; called by muse, mutect2, varscan2
- PPARA | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99415745; called by muse, mutect2, varscan2
- PRKDC | c.11840G>T p.G3947V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041972; called by muse, mutect2
- PRPF39 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100866030; called by muse, mutect2, varscan2
- PTPRZ1 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs375971673, COSV66440395; called by muse, mutect2, varscan2
- RFX6 | c.1781A>T p.H594L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100264078; called by muse, mutect2, varscan2
- RGR | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100812957; called by muse, mutect2, varscan2
- SAMD7 | c.1177T>C p.F393L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100157023; called by muse, mutect2, varscan2
- SEC14L1 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV101171134; called by muse, mutect2, varscan2
- SLC22A3 | c.1363T>A p.L455M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99279241; called by muse, mutect2, varscan2
- SLITRK2 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as COSV100158050; called by muse, mutect2, varscan2
- SLITRK2 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV100158052; called by muse, mutect2, varscan2
- SOX3 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1041580111, COSV100983739; called by muse, mutect2, varscan2
- SPATA17 | c.256A>C p.M86L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs144229899, COSV65124834; called by muse, mutect2, varscan2
- SPSB4 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV60149579; called by muse, mutect2, varscan2
- ST8SIA4 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | PolyPhen benign (0); catalogued as COSV51505485, COSV99185412; called by muse, mutect2, varscan2
- SUPT5H | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100781916, COSV100782119; called by muse, mutect2, varscan2
- TAB3 | c.125G>C p.C42S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916554; called by muse, mutect2, varscan2
- THOC2 | c.3333C>A p.C1111* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV99833861; called by muse, mutect2, varscan2
- TNNI3K | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100436594; called by muse, mutect2, varscan2
- TNNI3K | c.2011+1G>T p.X671_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100437439; called by muse, mutect2, varscan2
- TRIML1 | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs764350437, COSV100206197; called by muse, mutect2, varscan2
- TTN | c.13097G>A p.S4366N (on ENST00000591111; = p.S4320N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100623009; called by muse, mutect2, varscan2
- ZNF689 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as rs747806843, COSV99787863; called by muse, mutect2
- ZNHIT1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56183977, COSV99778166; called by muse, mutect2, varscan2
- BCHE | c.1494dup p.W499Vfs*12 | Frame Shift Ins (INS) | VAF 48/153 reads (31%) | called by mutect2, pindel, varscan2
- IBTK | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- KIR2DS4 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, varscan2
- NBEAL1 | c.5370del p.R1792Gfs*10 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- OR4C3 | c.4del p.D2? | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | called by mutect2, pindel, varscan2
- RYR3 | c.10456_10480del p.V3486Lfs*23 (on ENST00000389232; = p.V3487Lfs*23 on NM_001036.6) | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel
- SCN10A | c.2921T>C p.L974P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- SH3GL1 | c.843dup p.K282Qfs*19 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.378del p.S127Afs*20 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- ZBTB41 | c.465_466del p.P156Sfs*20 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- ALAS2 | c.771C>G p.S257= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV58188821; called by muse, mutect2, varscan2
- AMMECR1L | c.420G>A p.V140= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99761474; called by muse, mutect2
- ELMOD1 | c.120C>T p.I40= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV56190541, COSV99760288; called by muse, mutect2
- FAM189B | c.804C>T p.Y268= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100226850; called by muse, mutect2, varscan2
- GPAM | c.2256G>T p.L752= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100788340; called by muse, mutect2, varscan2
- GPR139 | c.960C>T p.S320= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV100429970; called by muse, mutect2, varscan2
- KRTAP6-1 | c.90G>T p.L30= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV58168743; called by muse, mutect2, varscan2
- OR5A1 | c.744G>A p.L248= | Silent (SNP) | VAF 64/240 reads (27%) | catalogued as COSV57378214; called by muse, varscan2
- PROX1 | c.1068G>C p.L356= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV99799943; called by muse, mutect2, varscan2
- RTEL1 | c.186C>T p.H62= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100542631; called by muse, mutect2, varscan2
- SNAI3 | c.795C>T p.Y265= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs370451683, COSV100178938; called by muse, mutect2, varscan2
- TTN | c.23820G>T p.L7940= (on ENST00000591111; = p.L7013= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100623008; called by muse, mutect2, varscan2
- USP29 | c.390C>T p.D130= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV54241000, COSV99572360; called by muse, mutect2, varscan2
- USP38 | c.1953C>T p.P651= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as rs761043259, COSV100189383, COSV61027628; called by muse, mutect2, varscan2
- ZNF229 | c.1674C>T p.D558= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs1460471992, COSV99350684; called by muse, mutect2, varscan2
- ZNF461 | c.1164G>A p.R388= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1305613135, COSV100831457, COSV64455309; called by muse, mutect2, varscan2
- ZNF609 | c.1527C>T p.I509= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100441499; called by muse, mutect2, varscan2
- C2orf83 | n.111dup | RNA (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- MIR891A | n.39A>G | RNA (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-1 | n.45G>A | RNA (SNP) | VAF 38/163 reads (23%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, varscan2
- TTN | c.10360+4258T>C | Intron (SNP) | VAF 18/96 reads (19%) | catalogued as rs1400907496, COSV100623011; called by muse, mutect2, varscan2
